TCGA case TCGA-GS-A9U4 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Fundacio Clinic per a la Recerca Biomedica. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0e251c03-bf86-4ed8-b45d-3cbc97160502

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Spain; Age at index: 27 years; Vital status: Dead; Days to death: 391 days (1.1 years).

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 27.6 years (10,075 days); Year of diagnosis: 2011; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 391 days (1.1 years); Ann Arbor extranodal involvement: No; Sites of involvement: Lymph Node, Supraclavicular / Lymph Node, Submandibular.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 3 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 22 days; Days to treatment end: 85 days; Number of cycles: 4.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cisplatin + Etoposide + Methylprednisolone + Rituximab; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP-21; Days to treatment start: 106 days; Days to treatment end: 110 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Lymph nodes of head, face and neck. Age at diagnosis: 27.9 years (10,181 days); Days to diagnosis: 106 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 106 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to progression: 106 days.
- Days to follow up: 391 days (1.1 years); Disease response: With Tumor.
- Imaging type: PET; Imaging result: Positive; Timepoint: Within 2 Months After Completion of First-Course Treatment.
- ECOG performance status: 0.

Molecular and laboratory tests
- ALK (IHC): Negative.
- BCL2 (IHC): Positive.
- BCL6 (IHC): Negative.
- CD10 (IHC): Negative.
- CD15 (IHC): Negative.
- CD20 (IHC): Positive.
- CD30 (IHC): Positive.
- CD5 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive.
- Immunoglobulin, Cytoplasmic (IHC): Equivocal.
- MYC loss (FISH): Positive.
- Epstein-Barr Virus (IHC): Positive.
- Lactate Dehydrogenase 385 IU [Blood test normal range upper: 450].
- Involved Tissue, NOS epstein-barr virus (ISH) 80% (Positive).

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Prednisone; Risk factor treatment: Yes; Risk factors: Behcet's Disease.
- Timepoint category: Initial Diagnosis; Weight: 50 kg; Height: 163 cm; BMI: 18.8.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Azathioprine; Risk factor treatment: Yes; Risk factors: Behcet's Disease.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GS-A9U4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 310 mg.
  Slide TCGA-GS-A9U4-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 95; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-GS-A9U4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GS-A9U4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Treatment outcome first course: Progressive Disease.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: History immunological disease other: Behget's disease.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 0; Bone marrow biopsy performed: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: supraclavicular; Lymph node involvement site: Submandibular.
- Tests performed: LDH level: 385; Mib 1 positive percent range: 51 - 75%; B cell genotype method: IgH PCR; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: CD79a; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunopheotypic analysis tested: CD15; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunopheotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunopheotypic analysis tested: ALK; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunopheotypic analysis tested: Cytoplasmic Ig; Immunophenotypic analysis method: Immunohistochemistry; Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc; Genetic abnormality results: Loss.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 4: Pharmaceutical therapy drug name: doxorubicina; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 6: Pharmaceutical therapy drug name: metilprednisona; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 7: Pharmaceutical therapy drug name: vincristina; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 8: Pharmaceutical therapy drug name: cisplatim; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 9: Pharmaceutical therapy drug name: ciclofosfamida; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.
- Drug treatment 10: Pharmaceutical therapy drug name: prednisona; Stem cell transplantation: No; Pharmaceutical regimen: CHOP-21 + Rituximab.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 391 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 391 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 106 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GS-A9U4-01A-11D-A38W-01): tumor purity 0.19, ploidy 2.19, whole-genome doublings 0.
